Somatic mutation profile of tumor specimen TCGA-DD-AAC9-01A (aliquot TCGA-DD-AAC9-01A-11D-A40R-10) from TCGA case TCGA-DD-AAC9, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 51.8 years (18,911 days).
Specimen TCGA-DD-AAC9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec807dcb-791e-45a0-8c2d-8b32fdb3daf5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAC9-10A (Blood Derived Normal), aliquot TCGA-DD-AAC9-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5ec5c5f-24f7-4f58-9d69-416ab1a03ceb

The open-access MAF lists 87 somatic variants for this specimen: 71 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 15, Nonsense Mutation 3, Splice Site 2, Frame Shift Del 2, In Frame Ins 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.4106A>C p.E1369A | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.41); catalogued as COSV99229420; called by muse, mutect2, varscan2
- ABCC8 | c.160C>T p.Q54* | Nonsense Mutation (SNP) | VAF 22/110 reads (20%) | catalogued as CM086731, COSV100217607; called by muse, mutect2, varscan2
- AMHR2 | c.1612G>T p.A538S | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as COSV99143454; called by muse, mutect2, varscan2
- AMPD1 | c.397G>C p.D133H | Missense Mutation (SNP) | VAF 8/229 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100815181; called by muse, mutect2
- ANKS1A | c.40G>T p.G14W | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100781073; called by muse, mutect2, varscan2
- ANOS1 | c.1813A>T p.I605F | Missense Mutation (SNP) | VAF 98/183 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV52925399; called by muse, mutect2, varscan2
- ARAP3 | c.4114C>T p.R1372* | Nonsense Mutation (SNP) | VAF 50/181 reads (28%) | catalogued as rs372420144; called by muse, mutect2, varscan2
- ARHGAP10 | c.246C>G p.C82W | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.338); catalogued as COSV100331653; called by muse, mutect2, varscan2
- ATP7A | c.1262A>G p.Y421C | Missense Mutation (SNP) | VAF 128/243 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100431443; called by muse, mutect2, varscan2
- BNIP3L | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.916); catalogued as COSV101020101; called by muse, mutect2, varscan2
- CCDC7 | c.1110A>G p.I370M | Missense Mutation (SNP) | VAF 120/402 reads (30%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.899); catalogued as COSV53235438; called by muse, mutect2, varscan2
- CDH7 | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV100543005; called by muse, mutect2, varscan2
- CDH7 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100543007; called by muse, mutect2, varscan2
- CDKN2A | c.257C>A p.A86D | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV58685895, COSV58689933, COSV58729271; called by muse, mutect2, varscan2
- CEP170 | c.814A>T p.I272L | Missense Mutation (SNP) | VAF 100/154 reads (65%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100317638; called by muse, mutect2, varscan2
- CSDE1 | c.359C>G p.P120R | Missense Mutation (SNP) | VAF 133/501 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as rs779821516, COSV54758626, COSV99795727; called by muse, mutect2, varscan2
- CTCFL | c.1102C>A p.R368S | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54770250, COSV99713149; called by muse, mutect2, varscan2
- DCST1 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99793550; called by muse, mutect2
- DCUN1D5 | c.616A>T p.T206S | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.17); catalogued as COSV99499223; called by muse, mutect2, varscan2
- DCXR | c.38C>T p.T13I | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100178906; called by muse, mutect2, varscan2
- DENND5A | c.805A>G p.I269V | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT tolerated (0.8); PolyPhen benign (0.024); catalogued as COSV100065110; called by muse, mutect2
- FARS2 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 177/736 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs145555213, CM160484, COSV99213147; called by muse, mutect2, varscan2
- FASN | c.566A>C p.N189T | Missense Mutation (SNP) | VAF 61/177 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.41); catalogued as COSV100148194; called by muse, mutect2, varscan2
- FGD3 | c.1286T>A p.I429N | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV100490793, COSV61599550; called by muse, mutect2, varscan2
- FKBP15 | c.860G>T p.R287M | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV99439510; called by muse, mutect2, varscan2
- H2AW | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 18/320 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.652); catalogued as rs1223770030, COSV100797310, COSV64209970; called by muse, mutect2
- HAS1 | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1568626418, COSV99708557; called by muse, mutect2, varscan2
- HAUS6 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 55/204 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.09); catalogued as COSV100998154; called by muse, mutect2, varscan2
- HECTD4 | c.1433T>C p.L478P | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101108271; called by muse, mutect2, varscan2
- HOXB4 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100203820; called by muse, mutect2, varscan2
- HSD17B8 | c.240G>T p.R80S | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100761844; called by muse, mutect2, varscan2
- KCND1 | c.1360G>A p.G454S | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.021); catalogued as COSV99502101; called by muse, mutect2, varscan2
- KDM5B | c.1232G>A p.W411* | Nonsense Mutation (SNP) | VAF 9/210 reads (4%) | catalogued as COSV99351206; called by muse, mutect2
- KIAA1109 | c.12301A>G p.N4101D | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV99169834; called by muse, mutect2, varscan2
- KLB | c.491T>C p.V164A | Missense Mutation (SNP) | VAF 5/151 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99962398; called by muse, mutect2
- KLHL3 | c.1114G>C p.D372H | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100553465, COSV59054214; called by muse, mutect2
- LVRN | c.1131C>A p.D377E | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.074); catalogued as rs748634842, COSV100773619; called by muse, mutect2, varscan2
- MAST4 | c.5632C>T p.P1878S (on ENST00000403625 / NM_001164664.2; = p.P1689S on NM_015183.3) | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); catalogued as COSV99843467, COSV99845332; called by muse, mutect2, varscan2
- MDN1 | c.3358A>G p.I1120V | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.444); catalogued as rs768681660, COSV101021688; called by muse, mutect2, varscan2
- MISP | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1004732824, COSV53119311; called by muse, mutect2, varscan2
- MMRN1 | c.1739C>A p.S580Y | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as COSV99307588; called by muse, mutect2, varscan2
- MRC2 | c.278G>A p.C93Y | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs919200382, COSV100316617; called by muse, mutect2
- NEU2 | c.53A>T p.H18L | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as COSV99290691; called by muse, mutect2, varscan2
- NFATC3 | c.1276G>T p.A426S | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100285588; called by muse, mutect2, varscan2
- NFIC | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV59413275; called by muse, mutect2, varscan2
- OR4N2 | c.845T>C p.L282S | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV100269887; called by muse, varscan2
- OR5L2 | c.128T>A p.L43Q | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV101004343, COSV101004389; called by muse, mutect2, varscan2
- OR8D4 | c.335G>A p.C112Y | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs1490886894, COSV100361907; called by muse, mutect2, varscan2
- PELP1 | c.684G>T p.L228F | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.799); catalogued as COSV99343255, COSV99343312; called by muse, mutect2, varscan2
- PHEX | c.2105G>A p.R702Q | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as rs1358095108, COSV101039518; called by muse, mutect2
- PSD4 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV99831388; called by muse, mutect2
- PTTG1 | c.583C>A p.P195T | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV100750936, COSV61677859; called by muse, mutect2, varscan2
- RAB3GAP2 | c.2981-2A>G p.X994_splice | Splice Site (SNP) | VAF 178/259 reads (69%) | catalogued as COSV100741411; called by muse, mutect2, varscan2
- RADX | c.1304-1G>T p.X435_splice | Splice Site (SNP) | VAF 37/70 reads (53%) | catalogued as COSV100998899; called by muse, mutect2, varscan2
- SEMA3C | c.1955A>G p.Q652R | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV99543612; called by muse, mutect2, varscan2
- SENP6 | c.391G>T p.V131L | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV100519471; called by muse, mutect2, varscan2
- SH2D5 | c.742G>C p.G248R (on ENST00000444387 / NM_001103161.2; = p.G164R on NM_001103160.2) | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV100903888; called by muse, mutect2, varscan2
- SLC17A4 | c.148A>G p.I50V | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1178354325, COSV100930653; called by muse, mutect2, varscan2
- SLC30A1 | c.227G>T p.R76L | Missense Mutation (SNP) | VAF 139/203 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65360500, COSV65361528; called by muse, mutect2, varscan2
- SLC9A2 | c.241C>A p.P81T | Missense Mutation (SNP) | VAF 65/199 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as COSV99296640; called by muse, mutect2, varscan2
- TCHH | c.1370G>T p.W457L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | PolyPhen benign (0); catalogued as COSV100915344; called by muse, mutect2, varscan2
- TLCD3B | c.22G>T p.G8W | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54226185, COSV99662562; called by muse, varscan2
- TMEM132D | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs757474690, COSV101398995, COSV70623917; called by muse, mutect2, varscan2
- YARS2 | c.506C>T p.T169I | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.029); catalogued as rs199769247, COSV100256516; called by muse, mutect2, varscan2
- ZNF787 | c.325C>G p.L109V | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99555691; called by muse, mutect2, varscan2
- ZNF99 | c.1408A>G p.K470E | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0.297); catalogued as COSV101233916; called by muse, mutect2, varscan2
- ADAMTS7 | c.4430G>C p.S1477T | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.604); called by muse, mutect2
- AFF4 | c.3472dup p.D1158Gfs*9 | Frame Shift Ins (INS) | VAF 43/214 reads (20%) | called by mutect2, pindel, varscan2
- PCDHB14 | c.824_833del p.G275Vfs*26 | Frame Shift Del (DEL) | VAF 23/97 reads (24%) | called by mutect2, pindel, varscan2
- RPP14 | c.340_341del p.L114Ifs*3 | Frame Shift Del (DEL) | VAF 18/89 reads (20%) | called by mutect2, pindel, varscan2
- USH2A | c.208_210dup p.S70dup | In Frame Ins (INS) | VAF 103/226 reads (46%) | called by mutect2, pindel, varscan2
- ACOX3 | c.24C>T p.G8= | Silent (SNP) | VAF 32/107 reads (30%) | catalogued as rs146635266; called by muse, mutect2, varscan2
- ARHGAP30 | c.2310G>A p.E770= | Silent (SNP) | VAF 126/178 reads (71%) | catalogued as COSV100920451; called by muse, mutect2, varscan2
- ARMC12 | c.570G>T p.V190= (on ENST00000373866 / NM_001286574.2; = p.V217= on NM_145028.5) | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as COSV99849562; called by muse, mutect2, varscan2
- COL4A4 | c.2841G>T p.R947= | Silent (SNP) | VAF 8/150 reads (5%) | catalogued as COSV100307466; called by muse, mutect2
- EVC | c.231G>A p.S77= | Silent (SNP) | VAF 20/112 reads (18%) | catalogued as rs140615894, COSV53833118; ClinVar: likely benign; called by muse, varscan2
- FCGBP | c.240C>A p.V80= | Silent (SNP) | VAF 33/142 reads (23%) | called by muse, mutect2, varscan2
- FSCN1 | c.465G>A p.L155= | Silent (SNP) | VAF 71/235 reads (30%) | catalogued as COSV100435268, COSV99058949; called by muse, mutect2, varscan2
- HBEGF | c.621C>T p.S207= | Silent (SNP) | VAF 5/109 reads (5%) | catalogued as COSV50182470; called by muse, mutect2
- ITPK1 | c.1110G>A p.A370= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs532039520, COSV99968719; called by muse, mutect2, varscan2
- MST1R | c.2028G>T p.L676= | Silent (SNP) | VAF 47/160 reads (29%) | catalogued as COSV99619416; called by muse, mutect2, varscan2
- PLEKHG4B | c.228T>A p.T76= (on ENST00000283426; = p.T432= on NM_052909.5) | Silent (SNP) | VAF 11/349 reads (3%) | catalogued as COSV99360881; called by muse, mutect2
- RAPGEF6 | c.2625G>A p.L875= | Silent (SNP) | VAF 44/138 reads (32%) | catalogued as COSV99727463; called by muse, mutect2, varscan2
- RIMS2 | c.417A>G p.K139= | Silent (SNP) | VAF 29/187 reads (16%) | catalogued as COSV101267328; called by muse, mutect2, varscan2
- SEMA3A | c.1515A>T p.S505= | Silent (SNP) | VAF 32/154 reads (21%) | catalogued as COSV99547681, COSV99547934; called by muse, mutect2, varscan2
- UNC45A | c.2133C>T p.A711= | Silent (SNP) | VAF 10/134 reads (7%) | catalogued as rs1299848455, COSV101263237; called by muse, mutect2
- LAMA4 | c.195+170T>C | Intron (SNP) | VAF 15/161 reads (9%) | catalogued as rs782309728, COSV99683833; called by muse, mutect2
